Surgical pathology report (de-identified scan), TCGA case TCGA-61-1736, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1736-01B (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS WITH BILATERAL ADNEXA, 398 GRAMS, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGOOOPHORECTOMY –

- A. PAPILLARY SEROUS CARCINOMA INVOLVING BOTH OVARIES (FIGO IIIC GRADE 3), ASSOCIATED OR ARISING IN A BACKGROUND OF ENDOMETRIOSIS (See comment).
- B. THE PATHOLOGIC TNM STAGE OF THIS TUMOR IS T3c N1 MX.
- C. UTERINE SEROSAL IMPLANTS OF PAPILLARY SEROUS CARCINOMA.
- D. RIGHT FALLOPIAN TUBE INVADDED BY DIRECT EXTENSION OF PAPILLARY SEROUS CARCINOMA.
- E. ANGIOLYMPHATIC INVASION IS PRESENT.
- F. CERVIX WITH MILD ATROPHY, EROSION AND NABOTHIAN CYST.
- G. PROLIFERATIVE ENDOMETRIUM.
- H. ADENOMYOSIS.

PART 2: LYMPH NODE, PELVIC, LEFT, EXCISION –

ONE LYMPH NODE, POSITIVE FOR METASTATIC PAPILLARY SEROUS ADENOCARCINOMA (1/1). WITH CAPSULAR INVASION.

PART 3: COLON, SIGMOID, NODULE, EXCISION –

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA WITH NECROSIS.

PART 4: APPENDIX, APPENDECTOMY –

- A. VERMIFORM APPENDIX WITH FIBROUS OBLITERATION AND SEROSAL METASTASES OF PAPILLARY SEROUS ADENOCARCINOMA.
- B. MESOAPPENDIX BIOPSY WITH METASTATIC ADENOCARCINOMA.

PART 5: ILEUM, TUMOR, EXCISION –

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

PART 6: OMENTUM, OMENTECTOMY –

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

Source: NCI Genomic Data Commons file 96a8532c-721c-4178-a989-42a0f9d63644 (TCGA-61-1736.C034E484-683B-463C-999D-EB1FD9741292.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).